TARGET case TARGET-40-0A4HX8 — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6c42a82c-4911-5457-b2b3-b15caf0f0406

Demographics
Sex at birth: male; Race: white; Age at index: 29 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 29.1 years (10,635 days); Year of diagnosis: 2003; Metastasis at diagnosis: No Metastasis; Days to last follow up: 3,050 days (8.4 years).
   Pathology details: Necrosis percent: 100.
   Treatment given: Protocol identifier: IHRT.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Ifosfamide.
   Treatment given: Therapeutic agents: Methotrexate.
   Treatment given: Therapeutic agents: Platinum.

Follow-up (2 entries)
- Days to follow up: 1,750 days (4.8 years); Year of follow up: 2011.
- Days to follow up: 3,050 days (8.4 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,050.

Biospecimens (2 samples)
- Sample TARGET-40-0A4HX8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-0A4HX8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 1750
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Histologic response: Stage 3/4 (91-100 % necrosis)
- Therapy: Pre-op Adria/Ifos/MTX + Adria/Plat; Post-op Adria/Plat + Adria/Ifos
